Somatic mutation profile of tumor specimen TCGA-ET-A40P-01A (aliquot TCGA-ET-A40P-01A-11D-A23M-08) from TCGA case TCGA-ET-A40P, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.4 years (11,843 days).
Specimen TCGA-ET-A40P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51a88cb0-c1bb-47d7-97f9-25b8f205f93a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A40P-10A (Blood Derived Normal), aliquot TCGA-ET-A40P-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91103817-53eb-4610-b20d-08220d1306b3

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852403, CM082642, CM910121, CM950395, COSV100811370; ClinVar: pathogenic; called by muse, mutect2
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 43/131 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DCAF12L2 | c.658T>A p.W220R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758507; called by muse, mutect2, varscan2
- DDX60 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs146995893; called by muse, mutect2
- KLHL22 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs570202770, COSV99839186; called by muse, mutect2, varscan2
- UNC13A | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs766769666, COSV53200961; called by muse, mutect2
- WNK2 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs778108051, COSV99941414; called by muse, mutect2, varscan2
- BCORL1 | c.4317_4318del p.Y1440Lfs*7 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | called by pindel, varscan2
